Somatic mutation profile of tumor specimen TCGA-OR-A5LD-01A (aliquot TCGA-OR-A5LD-01A-11D-A29I-10) from TCGA case TCGA-OR-A5LD, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 52.3 years (19,111 days).
Specimen TCGA-OR-A5LD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 142f08d9-5562-464b-92d6-b8136b5833df.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5LD-10A (Blood Derived Normal), aliquot TCGA-OR-A5LD-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/47f13f7d-57b3-4c15-bfb3-7eb09f5c8c7e

The open-access MAF lists 54 somatic variants for this specimen: 40 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 12, In Frame Del 3, Nonsense Mutation 2, Intron 1, Frame Shift Del 1, Translation Start Site 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALX1 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765386152, COSV100374254; called by muse, mutect2, varscan2
- BOP1 | c.1900_1902del p.N634del | In Frame Del (DEL) | VAF 60/321 reads (19%) | catalogued as rs1564593509; called by mutect2, pindel, varscan2
- C6orf58 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as rs757715087, COSV61667039, COSV61667266; called by muse, mutect2, varscan2
- CDIPT | c.637_639del p.K213del | In Frame Del (DEL) | VAF 31/130 reads (24%) | catalogued as rs753424031; called by pindel, varscan2
- ERF | c.398C>T p.P133L | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as COSV99724889; called by muse, mutect2, varscan2
- GLI2 | c.4255G>A p.A1419T (on ENST00000361492 / NM_001374353.1; = p.A1436T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/285 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs376388820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LSM3 | c.20A>C p.Q7P | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs200658802; called by muse, mutect2, varscan2
- LZTFL1 | c.72G>C p.K24N | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.377); catalogued as COSV56111448; called by muse, mutect2, varscan2
- NXPH2 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs1226089456; called by muse, mutect2
- STIM2 | c.485A>G p.N162S | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as rs1205845580; called by muse, mutect2, varscan2
- THOC1 | c.-2_1del | Translation Start Site (DEL) | VAF 8/42 reads (19%) | catalogued as rs1190358404; called by pindel, varscan2
- TIMP3 | c.602dup p.D202Gfs*2 | Frame Shift Ins (INS) | VAF 18/58 reads (31%) | catalogued as rs749890843; called by mutect2, varscan2
- TRPC6 | c.202C>T p.R68W | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as rs754919065, COSV100723720; called by muse, mutect2, varscan2
- TTC16 | c.2557G>A p.G853R | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.077); catalogued as rs780257760; called by muse, mutect2
- ZNF420 | c.1946G>A p.G649E | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as rs1225474983; called by muse, mutect2, varscan2
- CAPRIN1 | c.378_379del p.I127Kfs*15 | Frame Shift Del (DEL) | VAF 12/53 reads (23%) | called by mutect2, pindel, varscan2
- CEP43 | c.683C>G p.S228C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- COQ8B | c.188G>C p.R63P | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2
- CR2 | c.991A>T p.K331* | Nonsense Mutation (SNP) | VAF 20/142 reads (14%) | called by muse, varscan2
- DGKZ | c.889G>C p.D297H (on ENST00000454345 / NM_001105540.2; = p.D108H on NM_003646.4) | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- ESAM | c.61A>G p.S21G | Missense Mutation (SNP) | VAF 43/148 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRMD8 | c.829G>A p.D277N | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- FRMD8 | c.920G>C p.R307T | Missense Mutation (SNP) | VAF 36/226 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0.107); called by muse, varscan2
- GLB1L2 | c.1224G>C p.K408N | Missense Mutation (SNP) | VAF 17/89 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HMCN1 | c.12467C>T p.S4156L | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IQSEC1 | c.1331C>G p.P444R | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- MAP2 | c.565G>T p.G189C | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- MME | c.1709C>A p.S570Y | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- MUC16 | c.35897C>G p.T11966S | Missense Mutation (SNP) | VAF 94/284 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.849); called by muse, mutect2, varscan2
- OR52I2 | c.845A>C p.Y282S | Missense Mutation (SNP) | VAF 48/205 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PANK2 | c.142C>G p.L48V | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- PCARE | c.616C>G p.H206D | Missense Mutation (SNP) | VAF 8/156 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2
- RNF165 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by mutect2, varscan2
- SCG3 | c.565C>G p.L189V | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC24A4 | c.956T>A p.F319Y | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SP140 | c.274A>T p.T92S | Missense Mutation (SNP) | VAF 28/228 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, varscan2
- TNR | c.3941A>T p.E1314V | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TTC16 | c.1858A>G p.T620A | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZFAT | c.825C>A p.Y275* | Nonsense Mutation (SNP) | VAF 13/314 reads (4%) | called by muse, mutect2
- ZNF226 | c.1421_1423del p.S474del | In Frame Del (DEL) | VAF 20/128 reads (16%) | called by mutect2, pindel, varscan2
- AACS | c.306A>C p.A102= | Silent (SNP) | VAF 35/148 reads (24%) | called by muse, mutect2, varscan2
- CLCA4 | c.1050T>C p.D350= | Silent (SNP) | VAF 47/136 reads (35%) | called by muse, mutect2, varscan2
- DNMT1 | c.2577C>T p.D859= | Silent (SNP) | VAF 33/163 reads (20%) | catalogued as rs200928585; ClinVar: likely benign; called by muse, mutect2, varscan2
- GTF3C1 | c.3147A>G p.P1049= | Silent (SNP) | VAF 22/126 reads (17%) | called by muse, mutect2, varscan2
- HDAC9 | c.1620A>G p.G540= | Silent (SNP) | VAF 35/175 reads (20%) | catalogued as rs370270521; called by muse, mutect2, varscan2
- KANK4 | c.2760A>T p.A920= | Silent (SNP) | VAF 43/133 reads (32%) | called by muse, varscan2
- MCRS1 | c.615C>T p.S205= | Silent (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- NLRP10 | c.576C>T p.T192= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as rs138681119, COSV100149868; called by muse, mutect2, varscan2
- PEX13 | c.1128C>T p.A376= | Silent (SNP) | VAF 29/157 reads (18%) | called by muse, mutect2, varscan2
- PTH1R | c.1182C>A p.A394= | Silent (SNP) | VAF 49/186 reads (26%) | called by muse, mutect2, varscan2
- SLC9A1 | c.879C>T p.L293= | Silent (SNP) | VAF 18/200 reads (9%) | catalogued as rs762529463; called by muse, mutect2
- TACC2 | c.903A>T p.T301= | Silent (SNP) | VAF 11/181 reads (6%) | called by muse, mutect2
- AKR1C1 | c.84+304T>C | Intron (SNP) | VAF 17/184 reads (9%) | called by muse, mutect2
- MIR512-2 | n.95C>T | RNA (SNP) | VAF 32/175 reads (18%) | called by muse, mutect2, varscan2
